Somatic mutation profile of tumor specimen MMRF_2546_1_BM_CD138pos (aliquot MMRF_2546_1_BM_CD138pos_T1_KHS5U_L12876) from MMRF case MMRF_2546, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.6 years (29,793 days).
Specimen MMRF_2546_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8044e0d1-21e2-4b4e-8b2d-ad07e5e9a0a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2546_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2546_1_PB_Whole_C2_KHS5U_L12877; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc465a15-0776-4e3e-8371-351d26098a55

The open-access MAF lists 129 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 28, Silent 16, Intron 13, 5'Flank 7, 5'UTR 6, RNA 4, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUTS2 | c.2058C>A p.F686L | Missense Mutation (SNP) | VAF 135/352 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV61400488; called by muse, mutect2, varscan2
- BCL7A | c.91T>A p.W31R | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs756357727; called by muse, mutect2, varscan2
- BTK | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM980282; called by muse, mutect2
- ECSIT | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs373135989; called by muse, mutect2, varscan2
- ENPEP | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs144015322; called by muse, mutect2, varscan2
- GPR50 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 169/183 reads (92%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs201701013; called by muse, mutect2, varscan2
- IGHV1-69 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.047); catalogued as rs11557983; called by muse, mutect2, varscan2
- IGHV2-70D | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1169792576; called by muse, varscan2
- IGLV5-45 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 48/91 reads (53%) | catalogued as rs766606257; called by muse, mutect2, varscan2
- IGLV5-45 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs139643222; called by muse, mutect2, varscan2
- KIFAP3 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs200643889, COSV63031245, COSV63035380; called by muse, mutect2
- PEG3 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1193532964; called by muse, mutect2, varscan2
- PLA2G6 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs375740918; called by muse, mutect2, varscan2
- RIF1 | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs761561195; called by muse, mutect2, varscan2
- SCARA5 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100108004; called by muse, mutect2, varscan2
- SETD1B | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as rs868306191, COSV57351973; called by muse, mutect2, varscan2
- SETD2 | c.5903C>T p.T1968I | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV57438306; called by muse, mutect2, varscan2
- SHANK3 | c.3230C>T p.P1077L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1243460635; called by muse, mutect2
- SLC6A12 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs769047126, COSV62884996; called by muse, mutect2
- SOGA3 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV64105523; called by muse, mutect2
- TMEM196 | c.192del p.K64Nfs*6 | Frame Shift Del (DEL) | VAF 77/134 reads (57%) | catalogued as rs759398828; called by mutect2, varscan2
- WASHC2A | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554874753; called by muse, varscan2
- ARID4B | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- C12orf56 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CNN3 | c.958T>A p.Y320N | Missense Mutation (SNP) | VAF 15/507 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); called by muse, mutect2
- CPEB4 | c.1630dup p.L544Pfs*11 | Frame Shift Ins (INS) | VAF 52/167 reads (31%) | called by mutect2, pindel, varscan2
- CREB5 | c.564G>A p.M188I (on ENST00000357727 / NM_182898.4; = p.M181I on NM_004904.3) | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CSRNP2 | c.1369dup p.T457Nfs*7 | Frame Shift Ins (INS) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- CYP4A11 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 161/350 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DIS3 | c.2026A>G p.K676E | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DOCK7 | c.5362-1G>C p.X1788_splice (on ENST00000635253 / NM_001367561.1; = p.X1757_splice on NM_033407.3) | Splice Site (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- FOXE3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GREB1L | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HMGB1 | c.150+3A>C | Splice Region (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- IFNG | c.224T>C p.F75S | Missense Mutation (SNP) | VAF 8/243 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IGLV4-69 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 91/166 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- IL6ST | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- KMT2B | c.5013C>G p.Y1671* | Nonsense Mutation (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- MITF | c.715G>A p.E239K (on ENST00000448226 / NM_006722.3; = p.E133K on NM_000248.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MPPED1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 172/450 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, varscan2
- NDST4 | c.1726T>C p.C576R | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- NF1 | c.8212T>G p.L2738V (on ENST00000358273 / NM_001042492.3; = p.L2717V on NM_000267.3) | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2
- OXR1 | c.136C>T p.P46S (on ENST00000442977 / NM_001198532.1; = p.P45S on NM_018002.3) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PANX1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- PTBP1 | c.935C>A p.A312D (on ENST00000349038 / NM_031991.4; = p.A338D on NM_002819.5) | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PTPN1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- RANBP10 | c.1768C>G p.L590V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SPTB | c.1795G>T p.G599W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- TIMP3 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.792); called by muse, mutect2
- TRAJ57 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- TUBB4B | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- USP34 | c.8056del p.Y2686Ifs*37 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- VPS13C | c.635C>A p.P212Q (on ENST00000644861 / NM_020821.3; = p.P169Q on NM_017684.5) | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ATP11C | c.2574A>G p.L858= | Silent (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- BCL11B | c.1389G>A p.A463= (on ENST00000357195 / NM_001282237.2; = p.A392= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs770636408; called by muse, mutect2, varscan2
- CFAP69 | c.2112T>G p.A704= | Silent (SNP) | VAF 61/94 reads (65%) | called by muse, mutect2, varscan2
- DDX60 | c.2172G>A p.K724= | Silent (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- FAM117B | c.60T>C p.G20= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1401183400; called by muse, mutect2, varscan2
- FBRSL1 | c.1128C>T p.H376= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1277537653; called by muse, mutect2
- GORASP1 | c.769C>T p.L257= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs778476076; called by muse, mutect2, varscan2
- GRIK4 | c.2604C>A p.V868= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- HCAR2 | c.486C>G p.L162= | Silent (SNP) | VAF 72/155 reads (46%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as rs1233195687; called by muse, varscan2
- NSUN3 | c.759C>T p.A253= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- PDGFRA | c.2811G>A p.P937= | Silent (SNP) | VAF 95/187 reads (51%) | catalogued as rs190260215; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, varscan2
- PLEKHA7 | c.2274C>T p.V758= | Silent (SNP) | VAF 60/145 reads (41%) | called by muse, mutect2, varscan2
- ROBO1 | c.4315A>C p.R1439= | Silent (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- TRPA1 | c.357C>T p.S119= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- ZNF679 | c.15G>A p.P5= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as rs746179983, COSV55379643, COSV55381620; called by muse, mutect2, varscan2
- AAMP | c.-30C>T | 5'UTR (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- ACACB | c.5670-549G>A | Intron (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- ADGRD1 | c.746-178C>T | Intron (SNP) | VAF 17/36 reads (47%) | catalogued as rs754409607; called by muse, mutect2, varscan2
- ARHGAP42 | c.*440del | 3'UTR (DEL) | VAF 4/24 reads (17%) | catalogued as rs202022806, COSV53974750; called by pindel, varscan2
- BCL7A | chr12:122021465 C>T | 5'Flank (SNP) | VAF 83/194 reads (43%) | catalogued as rs1407312759; called by muse, varscan2
- BCL7A | chr12:122021467 T>G | 5'Flank (SNP) | VAF 82/192 reads (43%) | called by muse, varscan2
- BCL7A | chr12:122021485 C>G | 5'Flank (SNP) | VAF 106/220 reads (48%) | catalogued as rs914023552, COSV55848041; called by muse, varscan2
- BNIP2 | c.*4917G>T | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-33853A>G | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- CDC7 | c.*826G>A | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- CDH4 | c.*323G>A | 3'UTR (SNP) | VAF 16/63 reads (25%) | catalogued as rs907564435, COSV64668625; called by muse, varscan2
- CDH7 | chr18:65880962 A>T | 3'Flank (SNP) | VAF 70/157 reads (45%) | called by muse, mutect2, varscan2
- CDH8 | c.*417G>C | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- CHRNB2 | c.-130_-129delinsC | 5'UTR (DEL) | VAF 92/329 reads (28%) | called by pindel, varscan2*
- COL10A1 | c.*548C>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | catalogued as rs1034613914; called by muse, mutect2, varscan2
- CST9 | c.*797C>T | 3'UTR (SNP) | VAF 89/185 reads (48%) | called by muse, mutect2, varscan2
- CTNND2 | c.2638-1097G>T | Intron (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- CTTNBP2NL | chr1:112461819 C>T | 3'Flank (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- CXCL14 | c.*466C>T | 3'UTR (SNP) | VAF 49/103 reads (48%) | catalogued as rs1358131147; called by muse, mutect2, varscan2
- DCP1B | c.320-3090G>C | Intron (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- DTX1 | chr12:113057661 T>G | 5'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- ELP6 | c.*284G>A | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- ENPEP | c.*60G>T | 3'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*967T>C | 3'UTR (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
- F11 | c.1577-71T>C | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs113415466; called by muse, varscan2
- FERD3L | chr7:19145542 C>T | 5'Flank (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2
- FGF1 | c.*2941G>T | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- FITM2 | c.*24A>G | 3'UTR (SNP) | VAF 252/531 reads (47%) | called by muse, mutect2, varscan2
- FLI1 | c.722-47C>T | Intron (SNP) | VAF 10/66 reads (15%) | catalogued as rs186138233; called by muse, mutect2, varscan2
- FTO | c.*5825C>T | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.656G>T | RNA (SNP) | VAF 119/297 reads (40%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.-34G>A | 5'UTR (SNP) | VAF 50/108 reads (46%) | catalogued as rs1469661878; called by muse, varscan2
- IST1 | c.*266C>T | 3'UTR (SNP) | VAF 62/123 reads (50%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4411T>A | 3'UTR (SNP) | VAF 40/85 reads (47%) | called by muse, mutect2, varscan2
- LRRC15 | c.*651C>T | 3'UTR (SNP) | VAF 60/112 reads (54%) | catalogued as COSV100752682; called by muse, mutect2, varscan2
- LRRC55 | c.*2193G>A | 3'UTR (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- MAGEC2 | c.-16T>A | 5'UTR (SNP) | VAF 52/55 reads (95%) | called by muse, mutect2, varscan2
- MEF2C | c.*745T>C | 3'UTR (SNP) | VAF 11/87 reads (13%) | catalogued as rs1165505922; called by muse, mutect2, varscan2
- MEIS3P2 | n.250C>T | RNA (SNP) | VAF 47/117 reads (40%) | catalogued as rs1353893013; called by muse, mutect2, varscan2
- MIR1251 | n.11G>T | RNA (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- MLKL | c.1190+44A>G | Intron (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- NDST3 | c.*2606A>T | 3'UTR (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- NEFM | chr8:24913694 C>A | 5'Flank (SNP) | VAF 9/21 reads (43%) | catalogued as COSV55331975; called by muse, mutect2, varscan2
- NFASC | c.*4772A>G | 3'UTR (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- NSD3 | c.1856-1005G>C | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- PAPPA | c.*3277C>T | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- PCF11 | c.-70A>G | 5'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+4505A>T | Intron (SNP) | VAF 6/86 reads (7%) | catalogued as rs971588201, COSV65084074; called by muse, mutect2
- PHOX2A | c.-2C>T | 5'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- PIGF | c.-21-169del | Intron (DEL) | VAF 20/44 reads (45%) | called by pindel, varscan2
- PLA2G2F | c.*651G>A | 3'UTR (SNP) | VAF 91/207 reads (44%) | called by muse, mutect2, varscan2
- PPM1L | c.*6386C>A | 3'UTR (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- PRKCG | c.*423A>G | 3'UTR (SNP) | VAF 68/121 reads (56%) | called by muse, mutect2, varscan2
- PRRX2 | c.*304A>G | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853697 T>C | 5'Flank (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- SPRY3 | c.*1557T>C | 3'UTR (SNP) | VAF 137/156 reads (88%) | called by muse, mutect2, varscan2
- SYNGR2P1 | n.85C>T | RNA (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3430C>T | Intron (SNP) | VAF 59/143 reads (41%) | called by muse, mutect2, varscan2
- TXNDC5 | c.820-65_820-31del | Intron (DEL) | VAF 90/211 reads (43%) | called by mutect2, pindel*
- ZDHHC17 | c.*2482G>A | 3'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
